Somatic mutation profile of tumor specimen 0DC62Y from CCDI case PBBMCL, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 4.0 years (1,451 days).
Specimen 0DC62Y: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f6455ea3-385b-46f0-a57d-44a26660ec6c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DC636 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e68abdef-ad6f-41d1-849c-843bc5630ecf

The open-access MAF lists 3 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- OR8B8 | c.467C>T p.A156V | Missense Mutation (SNP) | VAF 11/278 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs1433390061, COSV60144504; called by muse, mutect2
- PCED1B | c.1162C>T p.R388C | Missense Mutation (SNP) | VAF 32/526 reads (6%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs1565622026, COSV71395058; called by muse, mutect2
- FSTL1 | c.806-58G>A | Intron (SNP) | VAF 24/82 reads (29%) | catalogued as rs564819042; called by muse, mutect2, varscan2
